Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JF, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JF-01A (Primary Tumor).

[page 1 of 2]
Requesting Doctor's Information:

LCD-0-3

Carcinoma, adrenal cortical
8370/3

Site: Adrenal Gland, cortex C74D

460 1/20/13

SPECIMEN TYPE: Adrenal

CLINICAL NOTES:

L) adrenal tumour ?ACC. Cushing's syndrome.

MACROSCOPIC:

'Left adrenal tumour'. The specimen consists of an adrenal gland 57 x 40 x 63mm, with associated fat 100 x 40 x 12mm. The tumour has been bisected prior to receipt. The total weight of the specimen including the periadrenal fat is 110g. The fat weighs approximately 30g and therefore the estimated weight of the adrenal tumour is 80g.

The cut surface of the adrenal tumour is tan and lobulated with two foci of cystic and haemorrhagic degeneration, 12mm in maximum dimension. The capsule appears otherwise intact. A wedge of tumour, 17 x 12 x 14mm has been removed prior to receipt. At the edge of the lesion there is a well-circumscribed area that is distinct from the lesion, 22 x 17 x 12mm. The cut surface of the tumour is inked green and the capsular surface and fat inked black. On sectioning, there is an area of haemorrhage/necrosis, 17 x 13 x 12mm in maximum dimension. Normal appearing adrenal gland is seen within the fat, and focally the tumour is seen to arise from the normal adrenal. Adjacent to the larger area of haemorrhage, is a well-circumscribed zone with a haemorrhagic centre, 12mm in maximum dimension. Macroscopically the lesion appears well-circumscribed. Representative sections in 15 blocks. Green ink covers the area where tumour was removed prior to receipt and does not indicate a true margin.

Blocks 1, 3&4: include normal adrenal gland

Blocks 2,3: paired

Blocks 5,6: haemorrhagic/necrotic area

Block 7: additional possible area of haemorrhage

Block 8-15: additional sections of adrenal lesion

MICROSCOPIC:

The 80g adrenal tumour is an ADRENAL CORTICAL CARCINOMA. The tumour is composed of variably pleomorphic cells. Most tumour cells have prominent nucleoli and some multi-nucleate tumour giant cells are present. Many of the cells have voluminous eosinophilic (oncocytic cytoplasm). Using the scoring system proposed by Weiss et al, the tumour would have a Weiss score of 4 due to high nuclear grade, atypical mitoses, predominantly eosinophilic cell type and capsular invasion. Tiny foci of necrosis are present but there is insufficient coagulative necrosis to warrant a point under the Weiss system. No sinusoidal or venous invasion is present. The mitotic rate is 4 mitoses per 50 hpf. Much of the tumour is confined to the adrenal, however there are unequivocal

HISTOPATHOLOGY

ANATOMICAL PATHOLOGY

[page 2 of 2]
Requesting Doctor's Information:

HISTOPATHOLOGY

SPECIMEN TYPE: Adrenal

areas of microscopic invasion into the extra-adrenal fat. Although the bulk of the tumour is separated from the soft tissue resection margin by an intact capsule, pseudocapsule or soft tissue plane, microscopically carcinoma extends to involve the soft tissue margins in a few areas.

The adrenal away from the carcinoma is normal.

Immunohistochemistry of the adrenal tumour is as follows:

IGF2: Negative

Ki-67: High proliferative index (up to 30% in areas)

Calretinin: Positive

Inhibin: Positive

MelanA: Positive

S-100: Negative

Chromogranin: Negative

SUMMARY:

Left adrenal tumour - Adrenal cortical carcinoma 80g.

REPORTING PATHOLOGIST:

(Electronic Signature)

ANATOMICAL PATHOLOGY

Page 2 of 2

Where 'Collected' indicates Rec:

No collection details given. Received details entered as collection details.

Source: NCI Genomic Data Commons file e1a3f810-cef0-4267-bf76-a1c65695dbc7 (TCGA-OR-A5JF.D9851FF2-70AC-45AD-AF18-B8A4B9F01E17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).